Somatic mutation profile of tumor specimen 0DSI9V from CCDI case PBCIDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,306 days).
Specimen 0DSI9V: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9534a39d-cc57-4c8c-b179-3374fed3f7a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI88 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0ef0f2c-93a9-4af4-b840-f4cdf080d8d0

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CGN | c.2824C>T p.R942* | Nonsense Mutation (SNP) | VAF 27/603 reads (4%) | catalogued as rs1417762574; called by muse, mutect2
- ESCO2 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 121/717 reads (17%) | catalogued as rs991672013, COSV59416534; called by muse, mutect2, varscan2
- PRLR | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 66/488 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754923118; called by muse, mutect2, varscan2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 40/1446 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- TTC12 | c.949G>T p.V317F | Missense Mutation (SNP) | VAF 85/681 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CASKIN2 | c.453C>T p.P151= | Silent (SNP) | VAF 14/479 reads (3%) | called by muse, mutect2
- TLR8 | c.2928A>T p.I976= (on ENST00000218032 / NM_138636.5; = p.I994= on NM_016610.4) | Silent (SNP) | VAF 83/711 reads (12%) | called by muse, mutect2, varscan2
- EMD | c.-65C>T | 5'UTR (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
